TCGA case TCGA-DC-6683 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectosigmoid junction; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/16a9e1c5-85c2-4930-a16c-af59114bac9a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 43 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C19; Tissue or organ of origin: Rectosigmoid junction; Site of resection or biopsy: Rectosigmoid junction; Classification of tumor: primary; Age at diagnosis: 43.6 years (15,918 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 762 days (2.1 years).
   Pathology details: Circumferential resection margin: 70; Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 27; Lymphatic invasion present: No; Non nodal tumor deposits: No; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 50 days; Days to treatment end: 214 days; Number of cycles: 12; Treatment dose: 28,800 mg; Prescribed dose: 2400; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 50 days; Days to treatment end: 214 days; Number of cycles: 12; Treatment dose: 9,600 mg; Prescribed dose: 800; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin Calcium; Treatment intent type: Adjuvant; Days to treatment start: 50 days; Days to treatment end: 214 days; Number of cycles: 12; Treatment dose: 9,600 mg; Prescribed dose: 800; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Adjuvant; Days to treatment start: 50 days; Days to treatment end: 214 days; Number of cycles: 12; Treatment dose: 1,980 mg; Prescribed dose: 170; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 153 days; Disease response: Tumor Free.
- Days to follow up: 306 days; Disease response: Tumor Free.
- Days to follow up: 762 days (2.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 11.1 ng/mL.
- MLH1 (IHC): Loss of Expression.
- MSH2 (IHC): Loss of Expression.
- MSH6 (IHC): Loss of Expression.
- PMS2 (IHC): Loss of Expression.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 82.6 kg; Height: 183 cm; BMI: 24.7.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DC-6683-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-DC-6683-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20.
  Slide TCGA-DC-6683-01A-01-BS1: Section location: Bottom; Percent tumor cells: 72; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 20.
- Sample TCGA-DC-6683-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DC-6683-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Rectum; Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 11.1; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: Yes.
- Loss expression of mismatch repair proteins by ihc results: Mismatch rep proteins loss IHC: MLH1-Not Expressed; Mismatch rep proteins loss IHC: MSH2-Not Expressed; Mismatch rep proteins loss IHC: PMS2-Not Expressed; Mismatch rep proteins loss IHC: MSH6-Not Expressed.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 3: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 762 days; disease-specific survival: no event (censored), 762 days; progression-free interval: no event (censored), 762 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DC-6683-01A-11D-1825-01): tumor purity 0.61, ploidy 3.18, whole-genome doublings 1.
